Gene-level copy-number profile of specimen HCM-SANG-1339-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1339-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1339-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06152f02-229c-4246-ab5c-78962879e40e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1339-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,385 have no estimate.
https://portal.gdc.cancer.gov/files/aab0d36a-7a97-4964-b62b-3bc73bbe8409

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,899; copy number 3: 27,684; copy number 4: 19,057; copy number 5: 6,198; copy number 6: 2,484; copy number 7: 254; copy number 8: 199; copy number 9: 129; copy number 10: 334.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 916 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes, copy number 8: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:100,159,244–100,656,448, 36 genes, copy number 8: GAL3ST4, GPC2, STAG3, CASTOR3, PVRIG, SPDYE3, PMS2P1, Y_RNA, STAG3L5P, STAG3L5P-PVRIG2P-PILRB, PILRB, PVRIG2P, MIR6840, PILRA, AC005071.1, ZCWPW1, MEPCE, AC092849.1, PPP1R35, PPP1R35-AS1, C7orf61, TSC22D4, NYAP1, AC069281.1, RN7SL416P, AGFG2, IRS3P, SAP25, AC069281.2, LRCH4, FBXO24, PCOLCE-AS1, PCOLCE, MOSPD3, TFR2, ACTL6B.
- chr8:39,451,045–39,522,852, 1 gene, copy number 7: ADAM3A.
- chr20:25,624,045–38,772,520, 305 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:41,024,205–64,327,972, 570 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
